Surgical pathology report (de-identified scan), TCGA case TCGA-56-8623, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8623-01A (Primary Tumor).

[page 1 of 2]
Surg Path Final Report

* Final Report *

* Final Report *

Final Diagnosis (Verified)

Right upper and middle lobes, excision:

Poorly differentiated squamous cell carcinoma - see comment.

Tumor size: 3.5 cm in greatest dimension.

Neoplasm is confined to pulmonary parenchyma, and abuts the visceral pleura.

No lymphovascular invasion identified.

Bronchial and vascular margins are free of neoplasm.

One (1) peribronchial lymph node shows anthracosis but no metastatic carcinoma.

AJCC stage: pT2a,N0.

Comment: Immunohistochemical phenotyping was performed on this patient's biopsy material and will not be repeated here.

Signature Line

Performing Lab (Verified)

Gross Description (Verified)

Printed by:

Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
Surg Path Final Report

* Final Report *

"A, Right upper lobe lung." The specimen consists of a 21.5 x 11 x 3.7 cm portion of lung. The pleura surface is red-gray. There is a 3.2 cm puckered area present on the pleural surface. This area will be inked black. On sectioning, there is a 3.5 x 2.8 x 1.3 cm ill-defined, firm, gray-white mass, which abuts the overlying pleural surface at the previously described puckered area and comes to within 3 cm of the bronchial margin. The remaining pleural parenchyma is red-brown and moderately congested. Mild emphysematous change is noted at the periphery of the specimen. No additional lesions or areas of interest are grossly identified. One peribronchial lymph node is identified. This measures 1.6 cm. "A1," bronchial and vascular margins; "A2-A3," mass with overlying pleura; "A4," mass with adjacent parenchyma; "A5," emphysematous change; "A6," peribronchial lymph node.

Signature Line

Clinical Information (Verified)

Small squamous cell carcinoma right lung.

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 5b0a3114-4133-4a87-aacd-97769c8103e4 (TCGA-56-8623.8D223B19-5EF0-4E25-814E-97CFE32AEA3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).